Somatic mutation profile of tumor specimen C3L-05480-03 (aliquot CPT0418450009) from CPTAC case C3L-05480, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.5 years (22,446 days).
Specimen C3L-05480-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca64524-5681-447a-899c-8a99173c0218.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05480-31 (Blood Derived Normal), aliquot CPT0419920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a68382dd-c111-4944-a540-6fafba0a4f31

The open-access MAF lists 90 somatic variants for this specimen: 60 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 26, Nonsense Mutation 5, Intron 2, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 98/450 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1333123411, COSV51850947; called by muse, mutect2
- BBOF1 | c.1104C>G p.H368Q | Missense Mutation (SNP) | VAF 100/382 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV101223973; called by muse, varscan2
- CNBD2 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 40/358 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs1237006123, COSV62588003; called by muse, mutect2, varscan2
- CYLC1 | c.790T>C p.W264R | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs1055555117; called by muse, mutect2, varscan2
- DPP10 | c.748A>T p.R250* | Nonsense Mutation (SNP) | VAF 39/322 reads (12%) | catalogued as COSV59701675; called by muse, mutect2, varscan2
- DYSF | c.2380G>A p.V794I | Missense Mutation (SNP) | VAF 35/414 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs371609233; ClinVar: uncertain significance; called by muse, mutect2
- EAF1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.789); catalogued as rs200760056, COSV67657305; called by muse, varscan2
- F2R | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 44/427 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs749663411, COSV100058433; called by muse, mutect2
- FAT4 | c.5443C>T p.R1815C | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766427266, COSV58670665; called by muse, mutect2
- GDF3 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 32/415 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372020374; called by muse, mutect2
- IGHE | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs367657749; called by muse, mutect2, varscan2
- IRX2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1300869223, COSV57412561; called by muse, mutect2
- JAKMIP3 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355503004, COSV53819585; called by muse, mutect2, varscan2
- MYH13 | c.5038C>T p.R1680C | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768403556, COSV52834895, COSV52839329; called by muse, mutect2, varscan2
- MYH7 | c.5690G>A p.R1897H | Missense Mutation (SNP) | VAF 77/417 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs727503240, COSV62519404; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NDUFAF1 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs770269434, COSV99531398; called by muse, mutect2
- OR51S1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100437546; called by muse, mutect2, varscan2
- PDGFRB | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.785); catalogued as rs368010583; called by muse, mutect2, varscan2
- PLEKHG4 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs766565971; called by muse, mutect2
- POLG | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 58/702 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.642); catalogued as rs1443866395; called by muse, mutect2
- POLM | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV54241790; called by muse, varscan2
- PRKCG | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 37/389 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs367543208; ClinVar: uncertain significance; called by muse, mutect2
- RBM15B | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 48/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60372929; called by muse, mutect2
- SCN10A | c.3758G>A p.R1253H | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs770705124; called by muse, mutect2, varscan2
- SIGLEC12 | c.491G>T p.G164V (on ENST00000291707 / NM_053003.4; = p.G46V on NM_033329.2) | Missense Mutation (SNP) | VAF 111/487 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757255714; called by muse, mutect2, varscan2
- SLC15A2 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 24/337 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1920305, COSV55202205; called by muse, mutect2
- SPINK5 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as rs1164247434; called by muse, mutect2, varscan2
- SPRED1 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1421262265; called by muse, mutect2, varscan2
- THAP9 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs762144579; called by muse, mutect2, varscan2
- UNC13C | c.5008G>T p.E1670* | Nonsense Mutation (SNP) | VAF 24/331 reads (7%) | catalogued as COSV99522235; called by muse, mutect2
- ZAN | c.7190G>A p.G2397D | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs1348512328; called by muse, mutect2, varscan2
- ZIC3 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 120/353 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV54972146; called by muse, mutect2, varscan2
- ZNF365 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs142196197; called by muse, mutect2, varscan2
- ZW10 | c.388_390del p.K130del | In Frame Del (DEL) | VAF 50/237 reads (21%) | catalogued as rs765692041; called by pindel, varscan2
- ANKRD30BL | c.118A>T p.R40W | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, varscan2
- CASP12 | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH2 | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CFAP61 | c.2788C>T p.Q930* | Nonsense Mutation (SNP) | VAF 26/360 reads (7%) | called by muse, mutect2
- GABRB2 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.688); called by mutect2, varscan2
- GAL3ST4 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GDF7 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 59/549 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- GPS2 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 79/356 reads (22%) | called by muse, mutect2, varscan2
- HRNR | c.5147G>A p.G1716D | Missense Mutation (SNP) | VAF 104/2592 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.055); called by muse, mutect2
- LRRC7 | c.2272T>G p.S758A (on ENST00000651989 / NM_001370785.2; = p.S725A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MYLK | c.821A>T p.E274V | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NAALADL2 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- OTOP3 | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PDS5B | c.3197A>G p.Y1066C | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PHLDA1 | c.463del p.V155Cfs*83 | Frame Shift Del (DEL) | VAF 101/433 reads (23%) | called by pindel, varscan2
- PLG | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPWD1 | c.1781dup p.T595Nfs*9 | Frame Shift Ins (INS) | VAF 31/223 reads (14%) | called by mutect2, pindel, varscan2
- PRPF18 | c.456C>G p.D152E | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB11FIP1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 20/575 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIMS1 | c.2102A>G p.E701G | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SLC36A3 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- SPTLC2 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2
- STXBP5L | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2
- USP53 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 67/415 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF208 | c.1103C>G p.P368R | Missense Mutation (SNP) | VAF 88/391 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANK2 | c.8139C>T p.V2713= | Silent (SNP) | VAF 54/263 reads (21%) | catalogued as rs564510599, COSV52174749; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKDD1B | c.1281G>A p.T427= | Silent (SNP) | VAF 41/364 reads (11%) | called by muse, mutect2, varscan2
- BAIAP3 | c.2079C>T p.H693= | Silent (SNP) | VAF 28/331 reads (8%) | catalogued as rs1175382376; called by muse, mutect2
- C10orf71 | c.2748A>G p.T916= | Silent (SNP) | VAF 71/376 reads (19%) | called by muse, mutect2, varscan2
- CLCNKA | c.1260C>T p.P420= | Silent (SNP) | VAF 72/387 reads (19%) | called by muse, mutect2, varscan2
- CMYA5 | c.6225G>A p.P2075= | Silent (SNP) | VAF 41/342 reads (12%) | catalogued as rs747877893, COSV71405897; called by muse, mutect2, varscan2
- DDX31 | c.1794G>A p.T598= | Silent (SNP) | VAF 30/348 reads (9%) | called by muse, mutect2
- FERMT3 | c.276C>T p.F92= | Silent (SNP) | VAF 49/399 reads (12%) | called by muse, mutect2, varscan2
- FUT11 | c.603G>C p.A201= | Silent (SNP) | VAF 117/558 reads (21%) | catalogued as rs372923597; called by muse, mutect2, varscan2
- HDAC4 | c.2197C>T p.L733= | Silent (SNP) | VAF 62/343 reads (18%) | called by muse, mutect2, varscan2
- LOXHD1 | c.2385C>T p.D795= | Silent (SNP) | VAF 37/421 reads (9%) | catalogued as rs531051635, COSV59663221; ClinVar: likely benign; called by muse, mutect2
- MEP1A | c.1053G>A p.T351= | Silent (SNP) | VAF 51/329 reads (16%) | catalogued as rs758895990, COSV57920133; called by muse, mutect2, varscan2
- NOS1AP | c.828G>A p.S276= | Silent (SNP) | VAF 98/541 reads (18%) | catalogued as rs756068745, COSV62633189; called by muse, varscan2
- PCDHA6 | c.1812C>T p.N604= | Silent (SNP) | VAF 33/389 reads (8%) | catalogued as rs782134190; called by muse, mutect2
- PIK3C2G | c.4359T>A p.I1453= (on ENST00000676171; = p.I1412= on NM_004570.5) | Silent (SNP) | VAF 32/316 reads (10%) | called by muse, mutect2
- PLXNB2 | c.90C>T p.S30= | Silent (SNP) | VAF 38/630 reads (6%) | catalogued as rs1393993397; called by muse, mutect2
- PRDM9 | c.1377G>A p.R459= | Silent (SNP) | VAF 100/415 reads (24%) | catalogued as rs112001060, COSV57006728, COSV57010936; called by muse, mutect2, varscan2
- PSMD8 | c.273G>A p.A91= | Silent (SNP) | VAF 72/378 reads (19%) | catalogued as COSV99286640; called by muse, mutect2, varscan2
- RHOXF1 | c.543C>T p.I181= | Silent (SNP) | VAF 62/188 reads (33%) | catalogued as rs1334417660, COSV99483898; called by muse, mutect2, varscan2
- SERPINA11 | c.403C>T p.L135= | Silent (SNP) | VAF 88/468 reads (19%) | called by muse, varscan2
- SIX2 | c.372C>T p.G124= | Silent (SNP) | VAF 84/448 reads (19%) | called by muse, mutect2, varscan2
- SLC52A2 | c.1152C>T p.G384= | Silent (SNP) | VAF 35/488 reads (7%) | catalogued as rs782168938; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- TSHZ3 | c.1002A>G p.P334= | Silent (SNP) | VAF 89/431 reads (21%) | called by muse, mutect2, varscan2
- VXN | c.318G>A p.G106= | Silent (SNP) | VAF 60/389 reads (15%) | called by muse, mutect2, varscan2
- WDR93 | c.1893C>T p.D631= | Silent (SNP) | VAF 36/516 reads (7%) | catalogued as rs1205619864; called by muse, mutect2
- XDH | c.2166G>A p.K722= | Silent (SNP) | VAF 43/240 reads (18%) | catalogued as COSV65151183; called by muse, mutect2, varscan2
- FAM13C | c.1332+37G>A | Intron (SNP) | VAF 52/279 reads (19%) | catalogued as rs1392622890; called by muse, mutect2, varscan2
- RGS4 | chr1:163069295 G>A | 5'Flank (SNP) | VAF 26/378 reads (7%) | called by muse, mutect2
- RPL37AP1 | chr20:44465255 C>T | 3'Flank (SNP) | VAF 10/236 reads (4%) | catalogued as rs1039917950; called by muse, mutect2
- SPATA13 | c.-222-25629C>A | Intron (SNP) | VAF 50/354 reads (14%) | called by muse, mutect2, varscan2
